Somatic mutation profile of tumor specimen ALCH-B0E3-TTP1-A (aliquot ALCH-B0E3-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0E3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.8 years (24,034 days).
Specimen ALCH-B0E3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c706111-7d1d-4c7b-98c6-64bc7ea8792f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0E3-NB1-A (Blood Derived Normal), aliquot ALCH-B0E3-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68f5358d-b609-423e-b53f-e3ceeb251936

The open-access MAF lists 416 somatic variants for this specimen: 302 protein-altering or splice-affecting, 77 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 249, Silent 77, Nonsense Mutation 22, Intron 17, Frame Shift Del 16, RNA 7, Splice Site 5, 3'UTR 4, Splice Region 4, 5'UTR 4, Frame Shift Ins 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.4879C>T p.R1627* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | hotspot (GDC flag); catalogued as rs1340793072, COSV71673166; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDCD10 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 61/402 reads (15%) | catalogued as rs1357917630, CM056679, COSV67102800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- STXBP1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 26/504 reads (5%) | catalogued as rs1057519501; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 58/207 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.3232G>A p.G1078S | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371807206; called by muse, mutect2, varscan2
- AL121899.2 | c.1780G>C p.V594L | Missense Mutation (SNP) | VAF 69/399 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748867939; called by muse, mutect2, varscan2
- ALG1L | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs773659009; called by muse, mutect2, varscan2
- ARHGAP28 | c.1811T>C p.V604A (on ENST00000383472 / NM_001366230.1; = p.V445A on NM_001010000.3) | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs1315172509; called by muse, mutect2, varscan2
- ARPP21 | c.726dup p.G243Rfs*2 | Frame Shift Ins (INS) | VAF 34/188 reads (18%) | catalogued as COSV51796534; called by mutect2, pindel, varscan2
- ATP10D | c.4165A>T p.S1389C | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV56696411; called by muse, mutect2, varscan2
- ATP2B2 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 80/455 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs753177348; called by muse, mutect2, varscan2
- BRWD3 | c.1932G>T p.E644D | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV64751000; called by muse, mutect2, varscan2
- C20orf144 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs918386274; called by muse, mutect2, varscan2
- C3 | c.3112G>C p.G1038R | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55582442; called by muse, mutect2, varscan2
- C9orf64 | c.52A>G p.S18G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100123486; called by muse, mutect2
- CARD10 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.637); catalogued as rs374641596; called by muse, mutect2, varscan2
- CCKBR | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV58100267; called by muse, mutect2, varscan2
- CD163 | c.1420+2T>A p.X474_splice | Splice Site (SNP) | VAF 18/97 reads (19%) | catalogued as COSV63130515; called by muse, varscan2
- CDCA3 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1555125529; called by muse, mutect2, varscan2
- CDHR5 | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs746807477, COSV57645560; called by muse, mutect2
- CDR1 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1326497568, COSV65164888; called by muse, mutect2, varscan2
- CELSR1 | c.4126G>C p.G1376R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53087920; called by muse, mutect2
- CFAP61 | c.1383C>G p.L461= | Splice Region (SNP) | VAF 24/113 reads (21%) | catalogued as rs142255939; called by muse, mutect2, varscan2
- CHM | c.1477T>C p.C493R | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773036937; called by muse, mutect2, varscan2
- CHRNG | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs748912147; called by muse, mutect2, varscan2
- CNTN1 | c.2005G>T p.V669L | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as COSV61636403; called by muse, mutect2, varscan2
- CNTRL | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53051955; called by muse, mutect2, varscan2
- COL18A1 | c.3696C>A p.N1232K (on ENST00000359759 / NM_130444.3; = p.N997K on NM_030582.4) | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368730788; called by muse, mutect2, varscan2
- COL22A1 | c.4346del p.P1449Rfs*6 | Frame Shift Del (DEL) | VAF 15/127 reads (12%) | catalogued as COSV100276593; called by mutect2, pindel
- COPB1 | c.1537A>T p.K513* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV51449537; called by muse, mutect2, varscan2
- CRTAC1 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs764306528; called by muse, mutect2, varscan2
- CTAG2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); catalogued as rs782709417, COSV55995694; called by muse, mutect2, varscan2
- CTNNA2 | c.878C>G p.T293R | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV100783680, COSV63593723; called by muse, mutect2
- CYP4F8 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57853213; called by muse, mutect2, varscan2
- DCC | c.677C>A p.A226E | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99079897; called by muse, mutect2
- FAM126A | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs1239168465, COSV101327190; called by muse, mutect2
- FAM210A | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100452336; called by muse, mutect2
- FAM9B | c.394-1G>C p.X132_splice | Splice Site (SNP) | VAF 8/112 reads (7%) | catalogued as COSV59119668; called by muse, mutect2
- FBXO3 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55765064; called by muse, mutect2, varscan2
- FGFR3 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as rs767900565, COSV53392384; called by muse, mutect2
- FSIP2 | c.5462C>T p.T1821I | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58091195; called by muse, mutect2, varscan2
- GBA | c.1440G>C p.K480N | Missense Mutation (SNP) | VAF 71/522 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1057519356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCNA | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.007); catalogued as rs779033693; called by muse, mutect2, varscan2
- GLA | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 74/467 reads (16%) | catalogued as CD160143; called by muse, mutect2, varscan2
- GLMP | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs766499648, COSV55296323; called by muse, mutect2
- HDAC4 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1559266470; called by muse, mutect2, varscan2
- HEATR4 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV58572355; called by muse, mutect2, varscan2
- HOXD3 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.929); catalogued as rs1354767307, COSV50884747; called by muse, mutect2, varscan2
- ITGBL1 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754090600, COSV66011111; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs756440690; called by muse, mutect2, varscan2
- KCNA4 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.036); catalogued as rs1344100601; called by muse, mutect2, varscan2
- KCNA5 | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV52906310; called by mutect2, varscan2
- KEAP1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as COSV50272179; called by muse, mutect2, varscan2
- KIAA0319 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.216); catalogued as COSV65498068, COSV65500239; called by muse, varscan2
- KIF21B | c.1405del p.D469Mfs*9 | Frame Shift Del (DEL) | VAF 27/269 reads (10%) | catalogued as COSV59763808; called by mutect2, varscan2
- KIR2DL4 | c.1046A>G p.Q349R (on ENST00000396284; = p.Q275R on NM_001080770.2) | Missense Mutation (SNP) | VAF 126/637 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1453251990; called by muse, mutect2, varscan2
- LRBA | c.8474G>A p.R2825Q | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs746707676, COSV63963911; called by muse, mutect2, varscan2
- LRCH1 | c.901T>C p.Y301H | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs201406758; called by muse, mutect2, varscan2
- MADD | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 86/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753381527, COSV60619910; called by muse, mutect2, varscan2
- MED12 | c.2083G>C p.G695R | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as COSV61334372; called by muse, mutect2
- MKRN3 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 36/202 reads (18%) | catalogued as COSV58810700; called by muse, mutect2, varscan2
- MMS22L | c.1208del p.R403Qfs*8 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as COSV51528034; called by pindel, varscan2
- MTFMT | c.688G>T p.G230* | Nonsense Mutation (SNP) | VAF 24/220 reads (11%) | catalogued as COSV99584385; called by muse, mutect2, varscan2
- MYOM1 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 101/325 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375858580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.2791G>C p.D931H | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs575044124; called by muse, mutect2
- NAV3 | c.1468C>A p.Q490K | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV57071146; called by muse, mutect2, varscan2
- NBEA | c.5198C>T p.S1733F | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.146); catalogued as COSV100083145; called by muse, mutect2, varscan2
- NDUFA12 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1296757776; called by muse, mutect2, varscan2
- NUP160 | c.3719C>T p.T1240M | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs535059681, COSV65854418; called by muse, mutect2, varscan2
- NXPH4 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1460374358; called by muse, varscan2
- NYAP2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56014060; called by muse, mutect2, varscan2
- OR10G7 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.824); catalogued as COSV57868979; called by muse, mutect2, varscan2
- OR2T2 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 68/602 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100737805, COSV61618009; called by muse, varscan2
- OR52A5 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100263364; called by muse, mutect2, varscan2
- OR5H6 | c.116G>T p.C39F (on ENST00000642105; = p.C23F on NM_001005479.2) | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV67351464; called by muse, mutect2, varscan2
- OR6K3 | c.440G>A p.R147H (on ENST00000368146; = p.R131H on NM_001005327.2) | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs140112633; called by muse, mutect2, varscan2
- PCDHGA7 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99540353; called by muse, mutect2, varscan2
- PDZD4 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51246259; called by muse, mutect2, varscan2
- PIK3CA | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV55903344; called by muse, varscan2
- PIKFYVE | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 26/624 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52238494, COSV52240922; called by muse, mutect2
- PLXNA3 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782350039, COSV63755014; called by muse, mutect2, varscan2
- PPFIA2 | c.3544C>T p.R1182* | Nonsense Mutation (SNP) | VAF 39/321 reads (12%) | catalogued as COSV100331364; called by muse, mutect2, varscan2
- PRDM2 | c.3659C>T p.T1220I | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs766150798; called by muse, mutect2
- PRDM5 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs762968750; called by muse, mutect2
- PRDM9 | c.2665G>T p.V889F | Missense Mutation (SNP) | VAF 71/413 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV57007888, COSV99690542; called by muse, mutect2, varscan2
- PRMT1 | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV101212264; called by muse, mutect2, varscan2
- QKI | c.286-5_286-1delinsTTTTT p.X96_splice | Splice Site (ONP) | VAF 8/77 reads (10%) | catalogued as COSV51700483; called by mutect2*, pindel
- RELN | c.9488C>G p.S3163C | Missense Mutation (SNP) | VAF 125/660 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs754901701, COSV58985327, COSV59010411; called by muse, mutect2, varscan2
- RGSL1 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV54265570; called by muse, mutect2, varscan2
- SEC24D | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1235485163, COSV54879026; called by muse, mutect2
- SLITRK2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.821); catalogued as COSV59423030; called by muse, mutect2, varscan2
- SPATA31E1 | c.2373G>C p.M791I | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.074); catalogued as COSV57791683; called by muse, mutect2, varscan2
- SPATA31E1 | c.2374G>T p.A792S | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV57793873; called by muse, mutect2, varscan2
- SPTA1 | c.6736T>C p.Y2246H | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1044002616; called by muse, mutect2
- STAB2 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66337840; called by muse, mutect2, varscan2
- TAFA1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 29/316 reads (9%) | catalogued as COSV72037446; called by muse, mutect2
- TANGO6 | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.714); catalogued as rs1238601090; called by muse, mutect2, varscan2
- TCEA1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as rs764136240; called by muse, mutect2, varscan2
- THYN1 | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV55539097; called by muse, mutect2
- TRHR | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100304827; called by muse, mutect2, varscan2
- TSC1 | c.1166del p.G389Efs*51 | Frame Shift Del (DEL) | VAF 51/438 reads (12%) | catalogued as rs397514832; ClinVar: not provided; called by mutect2, pindel, varscan2
- TTN | c.98653G>C p.E32885Q (on ENST00000591111; = p.E25461Q on NM_003319.4) | Missense Mutation (SNP) | VAF 27/464 reads (6%) | PolyPhen benign (0.001); catalogued as rs770742837; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- TYR | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as CM041480, COSV99635685; called by muse, mutect2
- UFC1 | c.255C>T p.D85= | Splice Region (SNP) | VAF 52/273 reads (19%) | catalogued as rs147604779; called by muse, mutect2, varscan2
- VWDE | c.4744G>C p.E1582Q | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.503); catalogued as COSV51735106, COSV51735254; called by muse, mutect2, varscan2
- WDR11 | c.3374C>G p.S1125* | Nonsense Mutation (SNP) | VAF 104/740 reads (14%) | catalogued as rs1305648146; called by muse, mutect2, varscan2
- ZNF208 | c.2670A>T p.K890N | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68104562; called by muse, mutect2, varscan2
- ZNF275 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as COSV64704799; called by muse, mutect2, varscan2
- ZNF536 | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs556954524, COSV62824617, COSV62826657; called by muse, mutect2, varscan2
- ABRACL | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AC109583.1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 76/398 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ACKR2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACOT12 | c.832G>C p.G278R | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.028); called by muse, mutect2
- ACTB | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 23/432 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY10 | c.1676T>C p.M559T | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG4 | c.5342_5343del p.T1781Kfs*4 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by pindel, varscan2
- ADGRG4 | c.8210C>T p.S2737L | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ANK3 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD50 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ARHGEF39 | c.576G>C p.Q192H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ARL14EPL | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ATP11C | c.3125T>A p.F1042Y | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- ATP13A1 | c.2223C>G p.H741Q | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATP2B1 | c.3589A>T p.T1197S | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BCL2L15 | c.20T>C p.F7S | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMP2K | c.1654C>G p.Q552E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2
- BTK | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- C21orf91 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- CAPN6 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CD1B | c.998del p.P333Hfs*13 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | called by mutect2, pindel
- CD1D | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPA | c.864_877del p.E289Nfs*16 | Frame Shift Del (DEL) | VAF 38/169 reads (22%) | called by mutect2, pindel
- CDC42BPG | c.3760G>C p.E1254Q | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKN2A | c.204_208del p.E69Qfs*49 | Frame Shift Del (DEL) | VAF 70/248 reads (28%) | called by mutect2, pindel, varscan2
- CERS2 | c.855del p.H286Ifs*23 | Frame Shift Del (DEL) | VAF 17/154 reads (11%) | called by mutect2, pindel, varscan2
- CLASP1 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CLN8 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLPTM1L | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.434); called by muse, mutect2
- CLTC | c.4404C>A p.N1468K | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CROCC | c.2605C>G p.R869G | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CSMD1 | c.1975G>A p.E659K (on ENST00000520002; = p.E658K on NM_033225.6) | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CTNND2 | c.2048C>A p.T683N | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CUL9 | c.2249A>T p.Q750L | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2A6 | c.1445C>G p.T482R | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.417); called by muse, mutect2
- DENND5B | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DISP2 | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DISP3 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DKC1 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DLC1 | c.4093C>G p.L1365V (on ENST00000276297 / NM_001348081.2; = p.L928V on NM_006094.5) | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- DNAH8 | c.2470A>G p.T824A | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC13 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DSCAML1 | c.2833C>A p.Q945K (on ENST00000321322; = p.Q885K on NM_020693.4) | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DUOX2 | c.514-5C>T | Splice Region (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.10702C>A p.Q3568K | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2
- EIPR1 | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ELANE | c.547C>A p.R183S | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ESX1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FAM186A | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FAT1 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
- FBXO17 | c.43T>A p.S15T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- FBXO43 | c.1359C>A p.S453R | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FMNL1 | c.50C>A p.P17Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FOSL1 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- FOXG1 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- FSD1 | c.1490A>G p.*497Wext*? | Nonstop Mutation (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2
- FZD5 | c.1424G>T p.R475L | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- G2E3 | c.865A>G p.I289V | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- GABRA2 | c.256-2A>T p.X86_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- GDPD2 | c.1482G>T p.W494C | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GJA10 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRAMD1B | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GRIK2 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRIN1 | c.386C>G p.S129W | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTP1 | c.45_66del p.C15Wfs*13 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- GUCY1A1 | c.1244T>G p.I415R | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- H3C1 | c.110A>T p.K37I | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- HHIPL1 | c.2178G>C p.K726N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HOMEZ | c.532_552del p.T178_E184del | In Frame Del (DEL) | VAF 38/311 reads (12%) | called by mutect2, pindel
- HTR5A | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HUWE1 | c.10771C>A p.H3591N | Missense Mutation (SNP) | VAF 85/491 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IFNA16 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IFT20 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ITGAL | c.2746A>G p.I916V | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KCTD19 | c.273G>T p.L91F | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2
- KDM2B | c.1539A>T p.E513D | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIAA0319 | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 38/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KIF16B | c.3480A>T p.Q1160H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KMT2C | c.2197dup p.S733Ffs*8 | Frame Shift Ins (INS) | VAF 20/214 reads (9%) | called by pindel, varscan2
- LATS1 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- LCAT | c.78G>A p.W26* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- LCT | c.1120A>T p.R374W | Missense Mutation (SNP) | VAF 62/430 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LILRA4 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 31/426 reads (7%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.979); called by muse, mutect2
- LONRF2 | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1B | c.10679G>T p.C3560F | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP1B | c.9158G>C p.R3053T | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LRRIQ4 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LRRTM4 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LZTS2 | c.932C>G p.S311* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- MAP3K1 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAST2 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 72/431 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- MORN3 | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL4 | c.497_498del p.P166Hfs*70 | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | called by mutect2, pindel, varscan2
- MS4A6A | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NEIL3 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- NLRP13 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2
- NPAS2 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- NPY5R | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR0B1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 84/473 reads (18%) | called by muse, mutect2, varscan2
- NSFL1C | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2
- NSMCE3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- OR2AT4 | c.962G>C p.*321Sext*? (on ENST00000305159; = p.*321Sext*17 on NM_001005285.2) | Nonstop Mutation (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- OR2F1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR2T27 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR4C15 | c.592A>T p.M198L (on ENST00000314644; = p.M144L on NM_001001920.2) | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- OR4D10 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5AR1 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 47/337 reads (14%) | called by muse, mutect2, varscan2
- OR6X1 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OR7E24 | c.718G>C p.V240L | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OTOGL | c.2668G>C p.V890L (on ENST00000547103; = p.V881L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PATJ | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH17 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PCDHA6 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- PDE3A | c.3164G>T p.C1055F | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PHTF2 | c.283A>T p.R95* (on ENST00000248550 / NM_001366089.1; = p.R57* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- PIK3R4 | c.3309C>A p.H1103Q | Missense Mutation (SNP) | VAF 57/374 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIN4 | c.118+5A>T | Splice Region (SNP) | VAF 55/247 reads (22%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4150-1G>A p.X1384_splice | Splice Site (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- PLN | c.37A>T p.R13* | Nonsense Mutation (SNP) | VAF 44/431 reads (10%) | called by muse, mutect2, varscan2
- PNPT1 | c.1579T>A p.Y527N | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLA1 | c.1493G>T p.W498L | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- POLE2 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- POLR2A | c.3445C>G p.R1149G | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- POLR3A | c.1080A>T p.R360S | Missense Mutation (SNP) | VAF 49/371 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PQBP1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.954); called by muse, mutect2
- PRDM4 | c.665A>C p.H222P | Missense Mutation (SNP) | VAF 80/535 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR12 | c.3583G>A p.E1195K (on ENST00000615927; = p.E2016K on NM_020719.3) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2
- PRXL2B | c.209G>C p.R70P (on ENST00000444521; = p.R40P on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PSG3 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTGDR2 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB39B | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASA1 | c.2097A>C p.K699N | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RC3H1 | c.3251G>A p.S1084N | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- RGPD4 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RIMBP3 | c.3158G>T p.R1053L | Missense Mutation (SNP) | VAF 99/886 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- RPGRIP1L | c.2021A>C p.Q674P | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- RS1 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 104/511 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RSF1 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); called by muse, mutect2
- RSPO4 | c.350A>T p.K117M | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- SCN5A | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SELP | c.2162G>A p.W721* | Nonsense Mutation (SNP) | VAF 41/225 reads (18%) | called by muse, mutect2, varscan2
- SERPINF2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SHOX | c.834C>A p.D278E | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIGLEC5 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- SLC35B3 | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2
- SLC6A17 | c.325dup p.I109Nfs*50 | Frame Shift Ins (INS) | VAF 29/215 reads (13%) | called by mutect2, pindel, varscan2
- SLC6A5 | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 143/572 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SMCO2 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by mutect2, varscan2
- SOX1 | c.1098C>A p.S366R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SPAG9 | c.3046G>T p.A1016S (on ENST00000262013 / NM_001130528.3; = p.A1002S on NM_003971.6) | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); called by muse, mutect2
- SPATA7 | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRCIN1 | c.3308C>T p.P1103L (on ENST00000621492; = p.P1069L on NM_025248.3) | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SSX3 | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ST6GAL2 | c.1505del p.D502Vfs*39 | Frame Shift Del (DEL) | VAF 55/312 reads (18%) | called by mutect2, pindel, varscan2
- STARD9 | c.6829G>C p.E2277Q | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- STAT2 | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- SYT6 | c.584C>A p.P195Q (on ENST00000610222 / NM_001366225.1; = p.P110Q on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- TAF1 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, varscan2
- TAF4 | c.596A>T p.N199I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TEX13A | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.714); called by muse, mutect2
- TIGD5 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TKTL1 | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMEM132D | c.3152C>A p.T1051N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- TRHDE | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM6 | c.1345G>C p.V449L | Missense Mutation (SNP) | VAF 46/484 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2
- TRPM6 | c.831A>T p.K277N | Missense Mutation (SNP) | VAF 49/471 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- TTN | c.84271A>G p.I28091V (on ENST00000591111; = p.I20667V on NM_003319.4) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.54779del p.P18260Hfs*41 (on ENST00000591111; = p.P10836Hfs*41 on NM_003319.4) | Frame Shift Del (DEL) | VAF 45/279 reads (16%) | called by mutect2, pindel, varscan2
- TTN | c.20375C>A p.S6792* (on ENST00000591111; = p.S5865* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- TUBB8 | c.409C>G p.H137D | Missense Mutation (SNP) | VAF 80/805 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- URB2 | c.4556A>T p.E1519V | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- USP25 | c.2930A>T p.K977M | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- VILL | c.659_669del p.M220Rfs*35 | Frame Shift Del (DEL) | VAF 34/368 reads (9%) | called by mutect2, pindel
- WAPL | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR87 | c.6077T>C p.M2026T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK3 | c.2626A>T p.N876Y | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- XKR4 | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XPNPEP2 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 87/514 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB8B | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZIC2 | c.501del p.P168Rfs*50 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel
- ZIK1 | c.904A>T p.K302* | Nonsense Mutation (SNP) | VAF 10/185 reads (5%) | called by muse, mutect2
- ZNF260 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF280C | c.1624C>G p.P542A | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.354); called by muse, mutect2
- ZNF487 | c.51A>T p.K17N | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF630 | c.1371A>C p.K457N | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.152); called by muse, mutect2
- ZNF728 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF729 | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF750 | c.12_15delinsTTT p.K5Lfs*40 | Frame Shift Del (DEL) | VAF 57/256 reads (22%) | called by pindel, varscan2*
- ZSCAN18 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ANO3 | c.897C>T p.F299= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- ART5 | c.642T>C p.S214= | Silent (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
- ASTN2 | c.1095C>A p.I365= | Silent (SNP) | VAF 37/272 reads (14%) | catalogued as rs377391261, COSV104400819; called by muse, mutect2, varscan2
- ATP6V1H | c.372C>T p.P124= | Silent (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2, varscan2
- CARD9 | c.639C>G p.L213= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV53735383; called by muse, mutect2, varscan2
- CCDC157 | c.357G>A p.T119= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs555816649, COSV57839818; called by muse, mutect2, varscan2
- CCT4 | c.1557G>A p.L519= | Silent (SNP) | VAF 16/340 reads (5%) | called by muse, mutect2
- CDH20 | c.2268G>T p.V756= | Silent (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- CEP350 | c.2160A>G p.P720= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- CHCHD6 | c.585C>G p.P195= | Silent (SNP) | VAF 27/203 reads (13%) | called by muse, mutect2, varscan2
- CHGB | c.1641C>G p.L547= | Silent (SNP) | VAF 74/411 reads (18%) | called by muse, mutect2, varscan2
- DGKD | c.2145C>G p.L715= (on ENST00000264057 / NM_152879.3; = p.L671= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- DLGAP2 | c.942G>T p.V314= | Silent (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- DYNC1LI2 | c.1116G>A p.K372= | Silent (SNP) | VAF 46/268 reads (17%) | called by muse, mutect2, varscan2
- EBF1 | c.625C>A p.R209= | Silent (SNP) | VAF 34/260 reads (13%) | catalogued as rs749897481, COSV58166655; called by muse, mutect2, varscan2
- EGR2 | c.825C>G p.G275= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV54346554, COSV99654049; called by muse, mutect2, varscan2
- EHF | c.867G>A p.G289= | Silent (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- EHMT1 | c.1413G>A p.T471= | Silent (SNP) | VAF 28/454 reads (6%) | catalogued as rs772982687, CD063508, COSV58373241; called by muse, mutect2
- EPHA7 | c.594C>T p.V198= | Silent (SNP) | VAF 38/210 reads (18%) | called by muse, mutect2, varscan2
- ESRRG | c.820C>A p.R274= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs1217062997; called by muse, mutect2, varscan2
- GALNT3 | c.483C>T p.H161= | Silent (SNP) | VAF 13/200 reads (7%) | catalogued as rs1448251169; called by muse, mutect2
- GPC3 | c.1695C>T p.L565= | Silent (SNP) | VAF 15/362 reads (4%) | catalogued as rs1348658434; called by muse, mutect2
- GRAMD1B | c.592C>A p.R198= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV100455269, COSV59206704; called by muse, mutect2, varscan2
- GRIN2B | c.1890C>T p.I630= | Silent (SNP) | VAF 104/569 reads (18%) | catalogued as rs748829220, COSV101663015, COSV74205931; called by muse, mutect2, varscan2
- GRK3 | c.915G>T p.L305= | Silent (SNP) | VAF 42/266 reads (16%) | catalogued as COSV100151895; called by muse, mutect2, varscan2
- HEY1 | c.474C>G p.L158= | Silent (SNP) | VAF 58/284 reads (20%) | catalogued as COSV100559152, COSV61232817; called by muse, mutect2, varscan2
- IDE | c.18G>T p.A6= | Silent (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- IFNG | c.72G>A p.Q24= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- IGKV1D-16 | c.138G>T p.R46= | Silent (SNP) | VAF 130/1020 reads (13%) | catalogued as rs563402712; called by muse, mutect2, varscan2
- IRGM | c.202C>T p.L68= | Silent (SNP) | VAF 26/400 reads (7%) | called by muse, mutect2
- KCNA5 | c.315C>A p.G105= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV52906901; called by mutect2, varscan2
- KCNQ3 | c.1041A>G p.P347= | Silent (SNP) | VAF 56/513 reads (11%) | catalogued as rs936800044; called by muse, mutect2, varscan2
- KDM4C | c.1242A>G p.E414= | Silent (SNP) | VAF 62/395 reads (16%) | catalogued as rs774043706, COSV101185024; called by muse, mutect2, varscan2
- KIAA1755 | c.2865C>T p.L955= | Silent (SNP) | VAF 25/177 reads (14%) | catalogued as rs747536511, COSV54075546; called by muse, mutect2, varscan2
- LTBP2 | c.3609C>T p.C1203= | Silent (SNP) | VAF 31/247 reads (13%) | catalogued as rs778364270, COSV56206477; called by muse, mutect2, varscan2
- MAP1B | c.4716A>G p.P1572= | Silent (SNP) | VAF 37/170 reads (22%) | called by muse, mutect2, varscan2
- MSH4 | c.2698C>A p.R900= | Silent (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- MST1R | c.1011G>C p.L337= | Silent (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- MTX1 | c.798G>A p.K266= | Silent (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- MYH1 | c.3462G>T p.L1154= | Silent (SNP) | VAF 77/415 reads (19%) | called by muse, mutect2, varscan2
- NCOA1 | c.1992C>G p.S664= | Silent (SNP) | VAF 42/231 reads (18%) | called by muse, mutect2, varscan2
- NPC2 | c.321T>C p.Y107= | Silent (SNP) | VAF 32/546 reads (6%) | called by muse, mutect2
- OPN5 | c.897G>T p.A299= | Silent (SNP) | VAF 91/471 reads (19%) | catalogued as COSV55247275, COSV55247439; called by muse, mutect2, varscan2
- OR11H7 | c.912C>A p.V304= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- OR4C13 | c.24A>G p.T8= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV73648788; called by muse, mutect2
- OR4D10 | c.432C>T p.L144= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as rs1402779782; called by muse, mutect2, varscan2
- OR8B12 | c.57G>A p.Q19= | Silent (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- PAICS | c.735A>G p.V245= | Silent (SNP) | VAF 37/195 reads (19%) | catalogued as rs746070974; called by muse, mutect2, varscan2
- PHKA2 | c.801C>A p.A267= | Silent (SNP) | VAF 77/470 reads (16%) | called by muse, mutect2, varscan2
- PIM2 | c.123G>T p.G41= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- PRKCSH | c.1320G>T p.G440= | Silent (SNP) | VAF 55/274 reads (20%) | called by muse, mutect2, varscan2
- PRSS58 | c.714C>T p.I238= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- PTPN18 | c.1377G>T p.R459= | Silent (SNP) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- RAC3 | c.198G>A p.R66= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as rs1362590176; called by muse, mutect2, varscan2
- RPS6KA1 | c.2064C>T p.H688= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs1177066870; called by muse, mutect2, varscan2
- RTL3 | c.843T>C p.N281= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as rs1359891490; called by muse, mutect2, varscan2
- SAP130 | c.1524C>T p.T508= | Silent (SNP) | VAF 53/313 reads (17%) | called by muse, mutect2, varscan2
- SELE | c.1158C>A p.G386= | Silent (SNP) | VAF 49/293 reads (17%) | called by muse, mutect2, varscan2
- SHD | c.798C>T p.L266= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as rs975416726; called by muse, mutect2
- SIM1 | c.819C>T p.D273= | Silent (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- SMU1 | c.804C>T p.L268= | Silent (SNP) | VAF 27/236 reads (11%) | called by muse, mutect2, varscan2
- SP8 | c.678G>T p.A226= (on ENST00000361443 / NM_198956.4; = p.A244= on NM_182700.6) | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, varscan2
- SPACA4 | c.252C>T p.Y84= | Silent (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- SPATA31D1 | c.4017C>A p.T1339= | Silent (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- STARD13 | c.1959C>T p.P653= (on ENST00000336934 / NM_001243476.3; = p.P535= on NM_052851.3) | Silent (SNP) | VAF 36/216 reads (17%) | catalogued as rs751281044; called by muse, mutect2, varscan2
- TBC1D15 | c.1563C>T p.D521= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs940216074; called by muse, mutect2
- TENM1 | c.5421A>T p.T1807= | Silent (SNP) | VAF 21/130 reads (16%) | called by muse, varscan2
- TIMM8A | c.240A>T p.R80= | Silent (SNP) | VAF 65/476 reads (14%) | called by muse, mutect2, varscan2
- TIMP4 | c.579G>A p.Q193= | Silent (SNP) | VAF 114/612 reads (19%) | called by muse, mutect2, varscan2
- TMEM132D | c.1698C>T p.R566= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs757029767, COSV67160902; called by muse, mutect2, varscan2
- TUBB4A | c.252C>T p.I84= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV51152367; called by muse, mutect2, varscan2
- UACA | c.2046C>G p.V682= | Silent (SNP) | VAF 37/366 reads (10%) | called by muse, mutect2, varscan2
- UBN1 | c.1191G>A p.A397= | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as rs372644230; called by muse, mutect2, varscan2
- USP25 | c.1009C>T p.L337= | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- XIRP2 | c.7362C>A p.L2454= (on ENST00000628543; = p.L2629= on NM_152381.6) | Silent (SNP) | VAF 65/428 reads (15%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.3072G>C p.L1024= (on ENST00000605216 / NM_001242487.2; = p.L1029= on NM_015037.3) | Silent (SNP) | VAF 14/306 reads (5%) | called by muse, mutect2
- ZXDB | c.1413C>G p.L471= | Silent (SNP) | VAF 58/335 reads (17%) | called by muse, mutect2, varscan2
- AC002511.3 | chr19:35408619 C>G | 3'Flank (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2
- AC011294.1 | n.212G>A | RNA (SNP) | VAF 14/69 reads (20%) | catalogued as rs753401158; called by muse, mutect2, varscan2
- AC093802.1 | n.123G>T | RNA (SNP) | VAF 45/199 reads (23%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1360T>A | RNA (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27195740 G>C | 3'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- AL132655.6 | chr20:58840536 G>C | 5'Flank (SNP) | VAF 26/176 reads (15%) | catalogued as COSV58340672; called by muse, mutect2, varscan2
- AP003062.1 | n.917G>T | RNA (SNP) | VAF 76/562 reads (14%) | called by muse, varscan2
- ARHGEF4 | chr2:130916503 G>T | 5'Flank (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- COL5A1 | c.5136+44G>A | Intron (SNP) | VAF 57/298 reads (19%) | catalogued as rs767495961, COSV65664587; called by muse, mutect2, varscan2
- CYB5R2 | c.388+68C>G | Intron (SNP) | VAF 30/431 reads (7%) | catalogued as rs772515234; called by muse, mutect2
- EIF2B4 | c.590+13G>A | Intron (SNP) | VAF 61/384 reads (16%) | called by muse, mutect2, varscan2
- EXOSC10 | c.1801-59G>A | Intron (SNP) | VAF 48/322 reads (15%) | called by muse, mutect2, varscan2
- FBLN1 | c.80-26C>G | Intron (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- GLOD5 | c.-3G>T | 5'UTR (SNP) | VAF 24/116 reads (21%) | called by muse, varscan2
- IGFN1 | c.1242-3296dup | Intron (INS) | VAF 20/204 reads (10%) | called by pindel, varscan2
- IKBIP | c.297+7806G>A | Intron (SNP) | VAF 13/133 reads (10%) | catalogued as rs1440038076; called by muse, mutect2, varscan2
- ITLN2 | c.*10C>G | 3'UTR (SNP) | VAF 28/128 reads (22%) | catalogued as rs1308216971; called by muse, mutect2, varscan2
- LCN12 | c.550+76G>C | Intron (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.2781C>T | RNA (SNP) | VAF 30/608 reads (5%) | called by muse, mutect2
- MAP4K1 | c.*70G>A | 3'UTR (SNP) | VAF 25/221 reads (11%) | catalogued as COSV62095688; called by muse, mutect2, varscan2
- MPV17 | c.71-4057G>T | Intron (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12915T>C | Intron (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.-168C>T | 5'UTR (SNP) | VAF 45/193 reads (23%) | catalogued as rs1166718581; called by muse, mutect2, varscan2
- PHF5A | c.76+12A>T | Intron (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- PLOD1 | c.1903-25C>G | Intron (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- PPARA | c.711+14G>C | Intron (SNP) | VAF 76/404 reads (19%) | catalogued as rs757545271; called by muse, mutect2, varscan2
- PPFIA2 | c.1267-116dup | Intron (INS) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- PSTK | c.*188C>G | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- RPLP0P2 | n.1273C>A | RNA (SNP) | VAF 56/357 reads (16%) | called by muse, mutect2, varscan2
- RPS25 | c.-4C>T | 5'UTR (SNP) | VAF 32/303 reads (11%) | catalogued as COSV57723800; called by muse, mutect2
- SARS2 | c.962+26G>A | Intron (SNP) | VAF 23/524 reads (4%) | called by muse, mutect2
- TOX3 | c.87+27175T>A | Intron (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- UCHL5 | chr1:193059642 C>T | 5'Flank (SNP) | VAF 80/332 reads (24%) | catalogued as rs1387006522; called by muse, mutect2, varscan2
- ULK3 | c.103-196C>T | Intron (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- WASF4P | n.1201C>G | RNA (SNP) | VAF 13/62 reads (21%) | catalogued as rs1480498249; called by muse, mutect2, varscan2
- XIAP | c.*6065C>A | 3'UTR (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- ZNF253 | c.-76C>G | 5'UTR (SNP) | VAF 57/275 reads (21%) | called by muse, mutect2, varscan2
